Somatic mutation profile of tumor specimen HTMCP-03-06-02421-01A (aliquot HTMCP-03-06-02421-01A-01D-10409) from CGCI case HTMCP-03-06-02421, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3.
Specimen HTMCP-03-06-02421-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 44d251d2-28d9-460f-a1c8-ebd2a75c69dd.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02421-10A (Blood Derived Normal), aliquot HTMCP-03-06-02421-10A-01D-10409; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef819de2-ab21-4e5a-b520-5fb1da455982

The open-access MAF lists 83 somatic variants for this specimen: 60 protein-altering or splice-affecting, 15 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 15, Intron 5, Nonsense Mutation 4, Splice Region 2, RNA 2, 3'UTR 1, Splice Site 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIAPH3 | c.1825C>T p.P609S (on ENST00000400324 / NM_001042517.2; = p.P346S on NM_030932.3) | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs778580569; called by muse, mutect2, varscan2
- DOCK3 | c.5776G>A p.E1926K | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.037); catalogued as rs868974271; called by muse, mutect2, varscan2
- EP400 | c.3878C>T p.S1293F | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99042917; called by muse, mutect2, varscan2
- FREM1 | c.5734C>T p.R1912W | Missense Mutation (SNP) | VAF 67/219 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs747877946, COSV66529835; called by muse, mutect2, varscan2
- GPS2 | c.235C>G p.L79V | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100223251; called by muse, varscan2
- HLA-B | c.736del p.E246Rfs*51 | Frame Shift Del (DEL) | VAF 8/86 reads (9%) | catalogued as COSV69523177; called by pindel, varscan2
- KATNIP | c.865G>A p.V289I | Missense Mutation (SNP) | VAF 37/170 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751852302, COSV55189145; called by muse, mutect2, varscan2
- KIF21B | c.3565C>T p.R1189W | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); catalogued as rs376964063, COSV59754147; called by muse, mutect2, varscan2
- MAGI2 | c.3700G>A p.E1234K | Missense Mutation (SNP) | VAF 30/186 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV100833037; called by muse, mutect2, varscan2
- PCDHGA5 | c.32G>C p.G11A | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.006); catalogued as COSV99537264; called by muse, mutect2
- PIK3AP1 | c.1864G>A p.V622M | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV100225850; called by muse, mutect2, varscan2
- POT1 | c.342C>G p.I114M | Missense Mutation (SNP) | VAF 40/173 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.552); catalogued as rs989904335; called by muse, mutect2, varscan2
- POT1 | c.5C>G p.S2C | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); catalogued as COSV62928944; called by muse, mutect2, varscan2
- RB1 | c.2723G>A p.R908Q | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.984); catalogued as rs1432581053, COSV57328736; called by muse, mutect2, varscan2
- RBM14 | c.938C>T p.S313L | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.885); catalogued as rs773352601, COSV59559661; called by muse, mutect2
- RBM27 | c.1568C>G p.S523C | Missense Mutation (SNP) | VAF 32/185 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV54589119; called by muse, mutect2, varscan2
- SIPA1L1 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 46/222 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV62173831; called by muse, mutect2, varscan2
- SPEF2 | c.5314G>A p.A1772T | Missense Mutation (SNP) | VAF 56/150 reads (37%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.448); catalogued as rs142924757; called by muse, mutect2, varscan2
- SRRM2 | c.4409C>T p.P1470L | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV57068037; called by muse, mutect2, varscan2
- TTC21A | c.809C>G p.S270C | Missense Mutation (SNP) | VAF 62/292 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV57183030; called by muse, mutect2, varscan2
- WDFY3 | c.6782G>A p.R2261Q | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.213); catalogued as COSV55716232; called by muse, mutect2, varscan2
- XKR4 | c.1081C>T p.R361* | Nonsense Mutation (SNP) | VAF 21/137 reads (15%) | catalogued as rs867767654, COSV59340929; called by muse, mutect2, varscan2
- ZNF544 | c.1016C>T p.S339L | Missense Mutation (SNP) | VAF 54/267 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as COSV54134109; called by muse, mutect2, varscan2
- ZNF92 | c.802C>T p.R268W (on ENST00000328747 / NM_152626.4; = p.R199W on NM_007139.4) | Missense Mutation (SNP) | VAF 49/239 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.013); catalogued as rs766495649, COSV60875865; called by muse, mutect2, varscan2
- ARHGAP36 | c.823C>G p.Q275E | Missense Mutation (SNP) | VAF 34/181 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- CECR2 | c.4261C>T p.Q1421* (on ENST00000342247 / NM_001290047.2; = p.Q1237* on NM_001290046.1) | Nonsense Mutation (SNP) | VAF 14/85 reads (16%) | called by muse, mutect2, varscan2
- COL4A1 | c.4826G>C p.R1609T | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DMD | c.6619G>C p.E2207Q | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- EDC4 | c.3932dup p.C1311Wfs*18 | Frame Shift Ins (INS) | VAF 7/51 reads (14%) | called by mutect2, pindel, varscan2
- EIF4G3 | c.729G>C p.K243N | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- FLNC | c.6265G>A p.E2089K | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- GCM2 | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 12/317 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2
- GRM3 | c.502C>G p.Q168E | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HDAC2 | c.1162G>T p.D388Y | Missense Mutation (SNP) | VAF 41/196 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HIVEP1 | c.4884G>C p.Q1628H | Missense Mutation (SNP) | VAF 53/376 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- HNRNPR | c.1651C>G p.Q551E | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- LAMA2 | c.6874G>A p.D2292N | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- MARCHF6 | c.972+4A>G | Splice Region (SNP) | VAF 28/243 reads (12%) | called by muse, mutect2, varscan2
- MTTP | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MYO1B | c.1504G>A p.D502N | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- MYO5C | c.1465G>A p.D489N | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NLRP1 | c.3382G>A p.E1128K | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- NSD2 | c.4053G>T p.K1351N | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); called by muse, mutect2
- OR5L1 | c.566G>T p.C189F | Missense Mutation (SNP) | VAF 76/446 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- PAX7 | c.320G>C p.R107T | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- PCDH10 | c.2431G>T p.G811C | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHA5 | c.82G>A p.G28S | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- PPP1R12A | c.1174C>G p.P392A | Missense Mutation (SNP) | VAF 32/183 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRRC2B | c.3416C>G p.S1139* | Nonsense Mutation (SNP) | VAF 10/43 reads (23%) | called by muse, mutect2, varscan2
- RBM33 | c.949-6C>G | Splice Region (SNP) | VAF 6/52 reads (12%) | called by muse, varscan2
- RUVBL1 | c.430G>C p.E144Q | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.612); called by muse, mutect2
- SMG1 | c.10068G>C p.Q3356H | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNIP1 | c.328-1G>A p.X110_splice | Splice Site (SNP) | VAF 10/50 reads (20%) | called by muse, mutect2, varscan2
- SVIL | c.2908G>A p.E970K (on ENST00000355867 / NM_021738.3; = p.E544K on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/179 reads (15%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- SYNE1 | c.22976T>C p.M7659T (on ENST00000367255 / NM_182961.4; = p.M7588T on NM_033071.3) | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- TEX11 | c.279G>C p.Q93H (on ENST00000344304; = p.Q78H on NM_031276.3) | Missense Mutation (SNP) | VAF 31/171 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- TUBB2A | c.184C>G p.R62G | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- UBR5 | c.269C>G p.S90* | Nonsense Mutation (SNP) | VAF 17/105 reads (16%) | called by muse, mutect2, varscan2
- UNC79 | c.2419C>T p.L807F (on ENST00000393151 / NM_001346218.2; = p.L630F on NM_020818.5) | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- VCAN | c.5797G>A p.D1933N | Missense Mutation (SNP) | VAF 37/305 reads (12%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- ADAMTS20 | c.2988C>T p.N996= | Silent (SNP) | VAF 20/163 reads (12%) | called by mutect2, varscan2
- ADGRF5 | c.1479C>T p.I493= | Silent (SNP) | VAF 36/154 reads (23%) | catalogued as rs368648139; called by muse, mutect2, varscan2
- ADGRG4 | c.8721C>T p.L2907= | Silent (SNP) | VAF 43/267 reads (16%) | called by muse, mutect2, varscan2
- ARFGEF3 | c.717C>A p.L239= | Silent (SNP) | VAF 34/108 reads (31%) | called by muse, mutect2, varscan2
- ARFGEF3 | c.780C>G p.L260= | Silent (SNP) | VAF 17/118 reads (14%) | called by muse, mutect2, varscan2
- CERT1 | c.108C>T p.S36= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as rs1483632377; called by muse, mutect2, varscan2
- CHFR | c.1071C>T p.N357= (on ENST00000432561 / NM_001161345.1; = p.N316= on NM_018223.2) | Silent (SNP) | VAF 13/95 reads (14%) | called by muse, mutect2, varscan2
- DYNC1I2 | c.1234C>T p.L412= | Silent (SNP) | VAF 26/182 reads (14%) | called by muse, mutect2, varscan2
- DZIP1 | c.1710G>A p.L570= (on ENST00000347108; = p.L551= on NM_014934.5) | Silent (SNP) | VAF 10/292 reads (3%) | called by muse, mutect2
- ITGA8 | c.1344C>T p.S448= | Silent (SNP) | VAF 24/145 reads (17%) | catalogued as rs779402009; called by muse, mutect2, varscan2
- KPNA7 | c.1062G>A p.A354= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as rs770278283; called by muse, mutect2, varscan2
- MYO18A | c.1452G>A p.A484= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as rs770294431; called by muse, mutect2, varscan2
- OR5L1 | c.567C>T p.C189= | Silent (SNP) | VAF 76/443 reads (17%) | called by muse, mutect2, varscan2
- PRR14L | c.468G>A p.P156= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as rs777586838; called by muse, mutect2, varscan2
- RYR1 | c.8247G>A p.E2749= | Silent (SNP) | VAF 20/82 reads (24%) | called by muse, varscan2
- AC133485.7 | n.1123C>T | RNA (SNP) | VAF 22/256 reads (9%) | called by muse, mutect2
- ATP13A2 | c.*217C>T | 3'UTR (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2
- BBS9 | c.2632+23C>G | Intron (SNP) | VAF 34/222 reads (15%) | called by muse, varscan2
- CMSS1 | c.64+12435C>A | Intron (SNP) | VAF 26/102 reads (25%) | called by muse, mutect2, varscan2
- DLG2 | c.1978+3503G>T | Intron (SNP) | VAF 19/94 reads (20%) | called by muse, mutect2, varscan2
- DNAH17 | c.8511+2544G>A | Intron (SNP) | VAF 7/54 reads (13%) | catalogued as rs1046438734; called by muse, mutect2, varscan2
- MUC19 | n.12844C>T | RNA (SNP) | VAF 267/771 reads (35%) | catalogued as rs970880973; called by muse, mutect2, varscan2
- SPG7 | c.988-15G>C | Intron (SNP) | VAF 5/24 reads (21%) | catalogued as COSV99245304; called by muse, mutect2
